Somatic mutation profile of tumor specimen TCGA-D7-6518-01A (aliquot TCGA-D7-6518-01A-11D-1800-08) from TCGA case TCGA-D7-6518, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 75.5 years (27,594 days).
Specimen TCGA-D7-6518-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec6b5b7b-2a19-4a62-961c-83d29850383f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6518-10A (Blood Derived Normal), aliquot TCGA-D7-6518-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fac00c6-8c9e-430e-9e1c-0d5ee9c83866

The open-access MAF lists 71 somatic variants for this specimen: 50 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 19, Frame Shift Del 3, Nonsense Mutation 2, RNA 2, Splice Site 1, Frame Shift Ins 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1559183717, CM081493, COSV55602700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALOX5AP | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs148308449; called by muse, mutect2, varscan2
- ANKRD40 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV53335220; called by muse, mutect2, varscan2
- ASIC2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290030167, COSV63324569; called by muse, mutect2, varscan2
- CAND1 | c.2489C>G p.S830C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1325846883, COSV73389725, COSV73389802; called by muse, mutect2, varscan2
- CDC6 | c.573T>A p.C191* | Nonsense Mutation (SNP) | VAF 13/133 reads (10%) | catalogued as COSV52931635; called by muse, mutect2
- CDH1 | c.869A>G p.D290G | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55729578; called by muse, mutect2
- CELSR2 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV54780293; called by muse, mutect2
- CHI3L1 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55140401; called by muse, mutect2, varscan2
- DENND5A | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs965362811, COSV60238382; called by muse, mutect2
- DLL1 | c.1035T>A p.D345E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as COSV64538964; called by muse, mutect2, varscan2
- DSEL | c.1712C>A p.S571Y | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100025685; called by muse, mutect2
- EMB | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 9/191 reads (5%) | catalogued as COSV57484987; called by muse, mutect2
- EREG | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV55260673, COSV55262829; called by muse, mutect2, varscan2
- FANCI | c.2344T>G p.S782A | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV55535661; called by muse, mutect2, varscan2
- FMN2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs755620586, COSV60457466; called by muse, mutect2, varscan2
- HDLBP | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV60501703; called by muse, mutect2, varscan2
- HIPK4 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52519286; called by muse, mutect2
- HRNR | c.7981G>A p.G2661S | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs767125198; called by muse, varscan2
- IARS1 | c.3089C>G p.T1030R | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100986676, COSV65113577; called by muse, mutect2
- KBTBD6 | c.702G>C p.E234D | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV65272095; called by muse, mutect2, varscan2
- LAMA1 | c.245T>A p.I82K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67545171; called by muse, mutect2, varscan2
- LAMB1 | c.4318G>A p.A1440T | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs267601228, COSV55963509; called by muse, mutect2
- LRRK2 | c.3709T>G p.L1237V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV54173532; called by muse, mutect2
- MARK1 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs780288227, COSV65071924; called by muse, mutect2, varscan2
- OR1L4 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52341768; called by muse, varscan2
- PABPC5 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV57039174; called by muse, mutect2, varscan2
- PDE3A | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs532896888, COSV62973769; called by muse, mutect2
- PHF24 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.408); catalogued as rs1563936866, COSV54276488; called by muse, mutect2, varscan2
- PPARGC1A | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs767722215, COSV53532639; called by muse, mutect2, varscan2
- SEC24A | c.2727+1G>T p.X909_splice | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV67305326, COSV67306408; called by muse, mutect2, varscan2
- SETD2 | c.4622A>G p.N1541S | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV57439960; called by muse, mutect2, varscan2
- SPATA31A3 | c.3574dup p.T1192Nfs*14 | Frame Shift Ins (INS) | VAF 43/204 reads (21%) | catalogued as rs1301154937; called by mutect2, pindel, varscan2
- TASP1 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV61816366; called by muse, mutect2
- TMEM215 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV61364258; called by muse, mutect2
- TPP2 | c.2069T>G p.L690R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65755204; called by muse, mutect2, varscan2
- TRAPPC8 | c.3229C>T p.R1077W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs775221359, COSV51978222; called by muse, mutect2, varscan2
- TRIML1 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV60195954, COSV60197222; called by muse, mutect2, varscan2
- UGT2A1 | c.1419C>G p.H473Q | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV54147174; called by muse, mutect2, varscan2
- WDR90 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.623); catalogued as rs201191904, COSV53472786; called by muse, mutect2
- ZNF236 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773907012, COSV53499248; called by muse, mutect2, varscan2
- ZNF416 | c.1457G>T p.R486I | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52183719; called by muse, mutect2
- ZNF599 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV61397666; called by muse, mutect2, varscan2
- AKAP6 | c.133del p.D45Tfs*35 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- CSPG4 | c.419del p.L140Qfs*20 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- MED6 | c.295_300del p.Y99_I100del | In Frame Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- ROCK1 | c.557_558insTTT p.A185_L186insF | In Frame Ins (INS) | VAF 7/60 reads (12%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3533A>T p.K1178I | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2
- TMTC1 | c.2072_2087del p.A691Vfs*34 (on ENST00000539277 / NM_001193451.2; = p.A583Vfs*34 on NM_175861.3) | Frame Shift Del (DEL) | VAF 20/226 reads (9%) | called by mutect2, pindel
- AFF2 | c.3132C>G p.S1044= | Silent (SNP) | VAF 15/255 reads (6%) | catalogued as COSV54009966; called by muse, mutect2
- ANKRD55 | c.1134C>A p.V378= | Silent (SNP) | VAF 22/580 reads (4%) | catalogued as COSV61951275; called by muse, mutect2
- ATP2A1 | c.1600C>A p.R534= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV63922639; called by muse, mutect2, varscan2
- CORIN | c.705G>A p.P235= | Silent (SNP) | VAF 19/248 reads (8%) | catalogued as rs755107174, COSV56690711; called by muse, mutect2
- CRYBG2 | c.4374C>T p.I1458= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs369346813; called by muse, mutect2, varscan2
- DFFA | c.414C>T p.I138= | Silent (SNP) | VAF 7/153 reads (5%) | catalogued as COSV65478614; called by muse, mutect2
- DNMT3B | c.2343C>T p.I781= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV52424405; called by muse, mutect2, varscan2
- EDNRB | c.741C>T p.I247= (on ENST00000377211 / NM_001201397.1; = p.I157= on NM_000115.5) | Silent (SNP) | VAF 23/256 reads (9%) | catalogued as COSV57523565, COSV57528725; called by muse, mutect2
- HIVEP2 | c.612G>A p.L204= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV50022836, COSV50077887; called by muse, mutect2, varscan2
- LAMB2 | c.1257C>T p.D419= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs146643686; called by muse, mutect2
- LY6G6C | c.354C>G p.G118= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV65405496; called by muse, mutect2, varscan2
- NID1 | c.3552G>A p.T1184= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs546812606, COSV51629990, COSV99938292; called by muse, mutect2, varscan2
- PPP1R17 | c.216C>T p.H72= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV59612763; called by muse, mutect2
- RIC8B | c.732G>T p.V244= | Silent (SNP) | VAF 32/152 reads (21%) | catalogued as COSV62697412; called by muse, mutect2, varscan2
- SCAF1 | c.342C>T p.R114= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV62185276; called by muse, mutect2, varscan2
- SLC1A6 | c.1371G>A p.T457= | Silent (SNP) | VAF 52/148 reads (35%) | catalogued as rs780328846, COSV55669823; called by muse, mutect2, varscan2
- ZBTB39 | c.282A>G p.T94= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV55631143; called by muse, mutect2, varscan2
- ZMYM3 | c.3537C>T p.L1179= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV58741194; called by muse, mutect2, varscan2
- ZNF557 | c.327G>A p.V109= (on ENST00000414706 / NM_001044388.2; = p.V116= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV53275651; called by muse, mutect2, varscan2
- MIR379 | n.28G>A | RNA (SNP) | VAF 9/83 reads (11%) | catalogued as rs115827677; called by muse, mutect2, varscan2
- SNORD115-36 | n.46C>G | RNA (SNP) | VAF 16/520 reads (3%) | called by muse, mutect2
